Somatic mutation profile of tumor specimen ALCH-AF3Q-TTP1-A (aliquot ALCH-AF3Q-TTP1-A-3-0-D-A678-36) from ALCHEMIST case ALCH-AF3Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.6 years (27,258 days).
Specimen ALCH-AF3Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0c8098d-377a-4784-9064-628ab7823273.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AF3Q-NB1-A (Blood Derived Normal), aliquot ALCH-AF3Q-NB1-A-1-0-D-A678-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdc53ab2-0fd1-4bdc-9839-9d24fa9a7973

The open-access MAF lists 181 somatic variants for this specimen: 128 protein-altering or splice-affecting, 36 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 36, Nonsense Mutation 11, Intron 10, Splice Site 5, 3'UTR 4, RNA 3, Splice Region 3, Frame Shift Ins 1, Nonstop Mutation 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 31/245 reads (13%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.5114+1G>C p.X1705_splice | Splice Site (SNP) | VAF 14/160 reads (9%) | catalogued as rs878854457, CS122535; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 36/352 reads (10%) | catalogued as COSV64885524; called by muse, mutect2, varscan2
- C1QTNF2 | c.290G>A p.G97E (on ENST00000393975; = p.G52E on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220343907, COSV67433211; called by muse, mutect2, varscan2
- CACUL1 | c.694-1G>C p.X232_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100432437; called by muse, mutect2, varscan2
- CKM | c.1096_1098del p.K366del | In Frame Del (DEL) | VAF 18/170 reads (11%) | catalogued as rs780083622; called by pindel, varscan2
- CTDP1 | c.1301G>T p.R434L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV50003211; called by muse, mutect2, varscan2
- DBR1 | c.874A>G p.T292A | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457312344; called by muse, mutect2, varscan2
- DGKD | c.2795A>G p.H932R (on ENST00000264057 / NM_152879.3; = p.H888R on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1211593351; called by muse, mutect2, varscan2
- ELMO1 | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 14/223 reads (6%) | catalogued as COSV60324128; called by muse, mutect2
- FANCD2OS | c.283C>A p.R95S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs113633522, COSV55032647; called by muse, mutect2
- FARP1 | c.1961G>T p.G654V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV60335989; called by muse, mutect2, varscan2
- FASN | c.4991G>A p.R1664Q | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as rs199547232; called by muse, mutect2
- INPP4B | c.2355G>T p.M785I | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV53745320; called by muse, mutect2, varscan2
- JCAD | c.3920G>T p.S1307I | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV64759573; called by muse, mutect2, varscan2
- JPH2 | c.1925C>A p.A642D | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.143); catalogued as rs1202371777; called by muse, mutect2
- MAGED2 | c.909G>A p.S303= | Splice Region (SNP) | VAF 12/150 reads (8%) | catalogued as rs771039734; called by muse, mutect2
- MDGA2 | c.952G>A p.D318N (on ENST00000399232 / NM_001113498.2; = p.D20N on NM_182830.4) | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.196); catalogued as COSV100636639; called by muse, mutect2
- NHS | c.1300C>G p.L434V | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV66272883; called by muse, mutect2
- OR2W3 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV64457847; called by muse, mutect2, varscan2
- OR5T2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as rs137888738; called by muse, mutect2, varscan2
- PCLO | c.12008G>T p.G4003V | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763719224; called by muse, mutect2, varscan2
- PYROXD1 | c.667A>G p.R223G | Missense Mutation (SNP) | VAF 34/375 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs909582877; called by muse, mutect2
- RIMBP2 | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55471091; called by muse, mutect2, varscan2
- RRAGB | c.833A>C p.Y278S (on ENST00000262850 / NM_016656.4; = p.Y250S on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV53329029; called by muse, mutect2
- SCGB1D2 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as rs199544876, COSV55274791; called by muse, mutect2
- SENP2 | c.1112A>G p.D371G | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as COSV56194675; called by muse, mutect2, varscan2
- TECTA | c.4019C>A p.T1340N | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.697); catalogued as rs763657792; called by muse, mutect2, varscan2
- TEX12 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.094); catalogued as COSV99737719; called by muse, mutect2
- TRIM49C | c.949G>C p.D317H | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs532468553, COSV101442238; called by muse, mutect2, varscan2
- TRIO | c.9137A>T p.Q3046L | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100702488; called by muse, mutect2, varscan2
- TTC13 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); catalogued as COSV100792993; called by muse, mutect2
- TXNDC16 | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99909263; called by muse, mutect2
- ZNF407 | c.4361A>G p.Y1454C | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769513109; called by muse, mutect2
- ZNF609 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1252479896, COSV100441567; called by muse, mutect2
- ZNF716 | c.1222T>C p.Y408H | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1554324888; called by muse, mutect2
- ABCA13 | c.13235T>G p.L4412R | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ABCC11 | c.2804C>T p.P935L | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- ABCC9 | c.758T>C p.I253T | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ABCD2 | c.452T>C p.L151P | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ACAN | c.5322T>A p.Y1774* | Nonsense Mutation (SNP) | VAF 35/479 reads (7%) | called by muse, mutect2
- ALG13 | c.2537G>A p.G846E | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AMOT | c.2083G>T p.A695S (on ENST00000371959 / NM_001113490.1; = p.A286S on NM_133265.3) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKFN1 | c.1815G>C p.Q605H | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD52 | c.1955A>G p.K652R | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.378); called by muse, mutect2
- ARHGAP32 | c.2446G>A p.A816T (on ENST00000310343 / NM_001378025.1; = p.A467T on NM_014715.4) | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.003); called by muse, mutect2
- ARSF | c.1081G>T p.G361* | Nonsense Mutation (SNP) | VAF 17/154 reads (11%) | called by muse, mutect2
- ARSF | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP1A4 | c.2998T>C p.Y1000H | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.535); called by muse, mutect2
- BCORL1 | c.743C>A p.P248H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CACNA1A | c.4111G>C p.D1371H | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- CAMKK1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.333); called by muse, mutect2
- CATSPERE | c.1924G>T p.A642S | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); called by muse, mutect2
- CCDC141 | c.2129C>A p.A710E | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.586); called by muse, mutect2
- CCDC168 | c.6670C>T p.L2224F | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CDA | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- CHM | c.1797C>A p.C599* | Nonsense Mutation (SNP) | VAF 27/304 reads (9%) | called by muse, mutect2
- CLCN2 | c.1736G>T p.R579L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CLSPN | c.275T>C p.L92S | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.777); called by muse, mutect2
- COL26A1 | c.1233G>C p.K411N (on ENST00000313669 / NM_001278563.3; = p.K409N on NM_133457.4) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CRYBG3 | c.6920A>G p.Y2307C | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2
- CYLD | c.1519-2A>T p.X507_splice | Splice Site (SNP) | VAF 40/386 reads (10%) | called by muse, mutect2
- DCLRE1C | c.15G>C p.E5D | Missense Mutation (SNP) | VAF 33/405 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.033); called by muse, mutect2
- ESX1 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.255); called by muse, mutect2
- ESYT2 | c.680G>C p.G227A (on ENST00000613624; = p.G151A on NM_020728.3) | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- EYS | c.1420C>A p.P474T | Missense Mutation (SNP) | VAF 37/299 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- F11 | c.865+1G>T p.X289_splice | Splice Site (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- F13B | c.1004C>A p.A335D | Missense Mutation (SNP) | VAF 93/477 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- FAM135B | c.1186C>A p.L396M | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2
- FAP | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2
- FUT5 | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GABRA2 | c.1196A>G p.K399R | Missense Mutation (SNP) | VAF 40/514 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- GCNA | c.105T>C p.S35= | Splice Region (SNP) | VAF 17/196 reads (9%) | called by muse, mutect2
- GCNA | c.431A>T p.D144V | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); called by muse, mutect2
- GNE | c.146A>T p.N49I (on ENST00000396594 / NM_001128227.3; = p.N18I on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- GRIA2 | c.989G>C p.C330S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- HCFC1 | c.6013A>G p.K2005E | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- HDAC2 | c.1087A>T p.I363L | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2
- HIF1AN | c.429G>A p.R143= | Splice Region (SNP) | VAF 13/201 reads (6%) | called by muse, mutect2
- IGHV3-73 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- INPP5A | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2
- JMJD1C | c.2405G>C p.G802A | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- KCNA5 | c.1279T>A p.L427M | Missense Mutation (SNP) | VAF 17/277 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- KCNH7 | c.2209C>G p.Q737E | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LAMA2 | c.5717T>C p.V1906A | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.101); called by muse, mutect2
- LENG9 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- LTBP1 | c.2442_2443insT p.K815* (on ENST00000404816 / NM_206943.4; = p.K489* on NM_000627.4) | Frame Shift Ins (INS) | VAF 12/110 reads (11%) | called by mutect2, pindel, varscan2
- LYVE1 | c.603T>A p.C201* | Nonsense Mutation (SNP) | VAF 23/226 reads (10%) | called by muse, mutect2, varscan2
- MBOAT1 | c.187G>T p.V63F | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- MED12 | c.1819G>T p.D607Y | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NBPF12 | c.2675G>C p.R892T | Missense Mutation (SNP) | VAF 38/590 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- NLRP5 | c.659C>A p.A220E | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2
- NPFFR2 | c.475T>G p.F159V | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUDT11 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 13/131 reads (10%) | called by muse, mutect2, varscan2
- OGT | c.829C>A p.L277M | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2F2 | c.584A>T p.N195I | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- OR2T3 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTOG | c.3559G>T p.V1187L | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTUD5 | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCLO | c.14194G>C p.V4732L | Missense Mutation (SNP) | VAF 71/355 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PRSS12 | c.2463C>A p.C821* | Nonsense Mutation (SNP) | VAF 34/374 reads (9%) | called by muse, mutect2
- RIMS1 | c.1913T>A p.V638E | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ROBO3 | c.3101G>A p.G1034E | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RYR1 | c.2481G>T p.E827D | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- SEMA5B | c.1441G>T p.A481S | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.217); called by muse, mutect2
- SH2D4A | c.323A>T p.Q108L | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SLC44A5 | c.1154T>A p.I385N | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLCO1C1 | c.1975G>C p.A659P | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.025); called by muse, mutect2
- SNRPA1 | c.163A>G p.R55G | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2
- SNX33 | c.1725A>G p.*575Wext*64 | Nonstop Mutation (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- ST18 | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- STRN4 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TFAP2A | c.1177G>A p.V393M (on ENST00000482890; = p.V385M on NM_001032280.3) | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TIAM1 | c.3280T>C p.F1094L | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAF3IP1 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2
- TRDN | c.1783+2T>C p.X595_splice | Splice Site (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- TRIM58 | c.1248C>A p.D416E | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTLL6 | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- USP9X | c.5090_5094del p.L1697* | Frame Shift Del (DEL) | VAF 32/275 reads (12%) | called by mutect2, pindel
- WDR25 | c.151G>C p.A51P | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XIRP2 | c.8776G>T p.E2926* (on ENST00000628543; = p.E3101* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 23/258 reads (9%) | called by muse, mutect2
- ZFHX4 | c.7918C>A p.R2640S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by mutect2, varscan2
- ZKSCAN3 | c.70G>T p.V24F | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2
- ZNF253 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF280A | c.1074C>G p.I358M | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- ZNF518A | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZXDB | c.938G>C p.W313S | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRL3 | c.2004C>A p.G668= (on ENST00000506720 / NM_001322402.2; = p.G600= on NM_015236.6) | Silent (SNP) | VAF 24/256 reads (9%) | called by muse, mutect2
- C11orf96 | c.267G>A p.K89= | Silent (SNP) | VAF 15/142 reads (11%) | called by muse, varscan2
- CEBPE | c.843C>T p.S281= | Silent (SNP) | VAF 8/99 reads (8%) | called by muse, mutect2
- CREB5 | c.1146G>T p.L382= (on ENST00000357727 / NM_182898.4; = p.L375= on NM_004904.3) | Silent (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
- ELAPOR2 | c.2925G>T p.P975= (on ENST00000450689 / NM_001142749.3; = p.P808= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/298 reads (9%) | called by muse, mutect2
- FANCD2OS | c.282C>T p.I94= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV55039348, COSV99810784; called by muse, mutect2
- GLP1R | c.1083G>A p.G361= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2
- HMGB3 | c.258G>A p.K86= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- HTR3B | c.1278C>A p.I426= | Silent (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2
- INTS6 | c.690G>T p.G230= | Silent (SNP) | VAF 17/262 reads (6%) | catalogued as rs1260061027; called by muse, mutect2
- MAB21L3 | c.606G>T p.R202= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as rs1253963902; called by muse, mutect2
- MKX | c.405A>C p.P135= | Silent (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
- NAV3 | c.2004G>A p.Q668= | Silent (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2
- NDUFA5 | c.216T>G p.L72= | Silent (SNP) | VAF 57/372 reads (15%) | called by muse, mutect2, varscan2
- OCRL | c.246C>T p.C82= | Silent (SNP) | VAF 41/385 reads (11%) | called by muse, mutect2, varscan2
- OR14K1 | c.432T>A p.A144= | Silent (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- OR1L4 | c.817C>A p.R273= | Silent (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2, varscan2
- PLB1 | c.1527T>C p.F509= | Silent (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2
- PNLIP | c.918C>T p.N306= | Silent (SNP) | VAF 13/166 reads (8%) | catalogued as rs1168836564; called by muse, mutect2
- POU3F4 | c.669T>C p.Y223= | Silent (SNP) | VAF 16/258 reads (6%) | catalogued as rs1199790524; called by muse, mutect2
- SERPINE3 | c.609C>T p.S203= | Silent (SNP) | VAF 34/302 reads (11%) | catalogued as rs1288619379; called by muse, mutect2, varscan2
- SIDT1 | c.1464C>T p.P488= | Silent (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- SLC26A11 | c.105C>T p.P35= | Silent (SNP) | VAF 9/126 reads (7%) | catalogued as COSV100413455; called by muse, mutect2
- SMG1 | c.6615C>T p.I2205= | Silent (SNP) | VAF 38/381 reads (10%) | called by muse, mutect2
- SPP2 | c.69C>T p.N23= | Silent (SNP) | VAF 26/270 reads (10%) | catalogued as rs1315920333, COSV51446459; called by muse, mutect2
- STAG1 | c.21A>G p.P7= | Silent (SNP) | VAF 20/267 reads (7%) | called by muse, mutect2
- TMEM64 | c.1140A>G p.V380= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs1212613754, COSV69127921; called by muse, mutect2
- TRPV1 | c.1698C>T p.A566= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs762081731; called by muse, mutect2
- UBE2NL | c.153G>C p.G51= | Silent (SNP) | VAF 41/414 reads (10%) | called by muse, mutect2, varscan2
- USP34 | c.2994G>A p.L998= | Silent (SNP) | VAF 25/131 reads (19%) | called by muse, mutect2, varscan2
- WDR62 | c.124C>T p.L42= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as rs754167846; called by mutect2, varscan2
- XIRP2 | c.8152C>T p.L2718= (on ENST00000628543; = p.L2893= on NM_152381.6) | Silent (SNP) | VAF 20/264 reads (8%) | called by muse, mutect2
- ZNF329 | c.1110C>T p.P370= | Silent (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2, varscan2
- ZNF330 | c.840T>C p.D280= | Silent (SNP) | VAF 36/444 reads (8%) | called by muse, mutect2
- ZNF358 | c.612G>A p.A204= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1378363382; called by muse, varscan2
- ZNF613 | c.1191A>G p.E397= (on ENST00000293471 / NM_001031721.4; = p.E361= on NM_024840.4) | Silent (SNP) | VAF 26/271 reads (10%) | called by muse, mutect2
- AC073310.1 | n.792A>G | RNA (SNP) | VAF 35/174 reads (20%) | called by muse, mutect2, varscan2
- ACSM5 | c.*5C>A | 3'UTR (SNP) | VAF 18/128 reads (14%) | called by muse, varscan2
- ANKRD11 | c.87+3384G>A | Intron (SNP) | VAF 22/159 reads (14%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.428-16096T>A | Intron (SNP) | VAF 39/340 reads (11%) | called by muse, mutect2, varscan2
- C3P1 | n.3001C>T | RNA (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- CCDC150 | c.1441-142C>T | Intron (SNP) | VAF 21/210 reads (10%) | called by muse, mutect2, varscan2
- DDX56 | c.1566+42C>T | Intron (SNP) | VAF 19/125 reads (15%) | called by muse, mutect2, varscan2
- DLG5 | c.373+2152T>C | Intron (SNP) | VAF 26/165 reads (16%) | called by muse, mutect2, varscan2
- FAM183BP | n.805G>A | RNA (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- LRCH3 | c.2209-2933T>G | Intron (SNP) | VAF 57/610 reads (9%) | called by muse, mutect2
- LRCH3 | c.2209-2932C>A | Intron (SNP) | VAF 60/614 reads (10%) | called by muse, mutect2
- PACS1 | c.356+50221G>C | Intron (SNP) | VAF 18/176 reads (10%) | catalogued as rs746543336, COSV57699673; called by muse, mutect2, varscan2
- PRRT1 | c.20-63C>A | Intron (SNP) | VAF 36/340 reads (11%) | called by muse, mutect2, varscan2
- SSTR2 | c.*222C>A | 3'UTR (SNP) | VAF 29/209 reads (14%) | called by muse, mutect2, varscan2
- TNFRSF10B | c.*1271G>C | 3'UTR (SNP) | VAF 22/176 reads (13%) | called by muse, mutect2, varscan2
- UPRT | c.387-2012G>T | Intron (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- VPS37C | c.*943C>T | 3'UTR (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
